Somatic mutation profile of tumor specimen TCGA-BF-A3DL-01A (aliquot TCGA-BF-A3DL-01A-11D-A20D-08) from TCGA case TCGA-BF-A3DL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 84.3 years (30,805 days).
Specimen TCGA-BF-A3DL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d287206b-3a46-4e8d-8f54-41f8c7980f32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A3DL-10A (Blood Derived Normal), aliquot TCGA-BF-A3DL-10A-02D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82c821d1-163c-4f28-b604-d1ee3d5cb425

The open-access MAF lists 559 somatic variants for this specimen: 367 protein-altering or splice-affecting, 178 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 178, Nonsense Mutation 14, Splice Region 6, RNA 5, Frame Shift Del 5, Splice Site 3, 3'UTR 3, Intron 3, 3'Flank 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNA2 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553181323, COSV60369543; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ8 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 80/199 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV53715706; called by muse, mutect2, varscan2
- LDLR | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882106, CM100938, CM920460, COSV52942440; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199475693, CM136526, COSV61015308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 37/64 reads (58%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64672526; called by muse, mutect2, varscan2
- ABCB1 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55948271; called by muse, mutect2, varscan2
- ABCB5 | c.2948C>T p.S983L (on ENST00000404938 / NM_001163941.2; = p.S538L on NM_178559.6) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.613); catalogued as COSV51706637; called by muse, mutect2, varscan2
- ABCC6 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV52742772; called by muse, mutect2, varscan2
- ACAN | c.7201G>A p.E2401K (on ENST00000560601 / NM_001369268.1; = p.E2325K on NM_001135.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753135658, COSV61358506; called by muse, mutect2, varscan2
- ACSM1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54634358, COSV54635190; called by muse, mutect2, varscan2
- ACTR10 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs779037396, COSV54297852; called by muse, mutect2, varscan2
- ADA2 | c.1102G>A p.D368N (on ENST00000262607; = p.D127N on NM_177405.3) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1316855685, COSV52830910; called by muse, mutect2, varscan2
- ADAMTS18 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as COSV51403333, COSV99274082; called by muse, mutect2, varscan2
- ADAMTS20 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67129518; called by muse, mutect2, varscan2
- ADARB2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs867672739, COSV67219714; called by muse, mutect2
- ADNP | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.768); catalogued as COSV62424932; called by muse, mutect2, varscan2
- AGGF1 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as COSV57227576, COSV57228398; called by muse, mutect2, varscan2
- AGMO | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as COSV61108817; called by muse, mutect2, varscan2
- AGTR2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs202224363, COSV64156312; called by muse, mutect2, varscan2
- AL031681.2 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV100917020; called by muse, mutect2, varscan2
- AL592490.1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1313092571, COSV69425476; called by muse, mutect2, varscan2
- ALPK3 | c.4093+1G>A p.X1365_splice | Splice Site (SNP) | VAF 59/189 reads (31%) | catalogued as COSV51931809; called by muse, mutect2, varscan2
- ANKRD34B | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1427882176, COSV58613694; called by muse, mutect2, varscan2
- APOB | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV51930237, COSV51942531; called by muse, mutect2, varscan2
- ARAF | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV51691996; called by muse, mutect2, varscan2
- ARAP2 | c.2390G>A p.G797E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58284861; called by muse, mutect2, varscan2
- ARFGEF2 | c.4096T>C p.F1366L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV64211503; called by muse, mutect2, varscan2
- ASH1L | c.6266C>T p.S2089F (on ENST00000368346 / NM_001366177.2; = p.S2084F on NM_018489.3) | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64206767; called by muse, mutect2, varscan2
- ATCAY | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV56655130; called by muse, mutect2, varscan2
- ATRX | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs782633384, COSV64874141; called by muse, mutect2, varscan2
- AZGP1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs948529445, COSV52797423; called by muse, mutect2, varscan2
- BHMT | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV57154007; called by muse, mutect2, varscan2
- BRINP2 | c.2176C>T p.R726W | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756977841, COSV64175231; called by muse, mutect2, varscan2
- BRINP3 | c.1517G>T p.R506I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV66518638; called by muse, mutect2, varscan2
- BRPF1 | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.4); catalogued as COSV57404062; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C1QC | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs777624236, COSV65889431; called by muse, mutect2, varscan2
- C1orf56 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as COSV54846437; called by muse, mutect2, varscan2
- CACNA1E | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV62387981; called by muse, mutect2, varscan2
- CACNA1E | c.6019G>A p.D2007N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV62388000; called by muse, mutect2, varscan2
- CACNA1F | c.4787T>C p.F1596S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59903780; called by muse, mutect2, varscan2
- CACNA1H | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs377176081; called by muse, mutect2, varscan2
- CACNA2D1 | c.2195G>A p.R732Q (on ENST00000356253 / NM_001366867.1; = p.R720Q on NM_000722.4) | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs79127167, COSV62372664; called by muse, mutect2, varscan2
- CADM3 | c.653G>A p.G218E (on ENST00000368125 / NM_001127173.3; = p.G252E on NM_021189.5) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.102); catalogued as COSV63684792; called by muse, mutect2, varscan2
- CAPN11 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67236943; called by muse, mutect2, varscan2
- CARD11 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1402987893, COSV67798094; called by muse, mutect2, varscan2
- CASP5 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV52827743; called by muse, mutect2, varscan2
- CASR | c.2320T>G p.C774G (on ENST00000490131; = p.C851G on NM_000388.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM960246, COSV56136001; called by muse, mutect2, varscan2
- CD163 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63130971; called by muse, mutect2, varscan2
- CD1E | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV63769820, COSV63770568; called by muse, mutect2, varscan2
- CD22 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs763054158, COSV50050193, COSV50058335; called by muse, mutect2, varscan2
- CD86 | c.744G>A p.W248* (on ENST00000330540 / NM_175862.5; = p.W242* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV52605989; called by muse, mutect2, varscan2
- CDC14A | c.1266A>C p.K422N | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60556748; called by muse, mutect2, varscan2
- CDC42BPG | c.1954C>T p.L652= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV61346447; called by muse, mutect2, varscan2
- CDH1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs148400889; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH23 | c.5951C>T p.P1984L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56455338; called by muse, mutect2, varscan2
- CDYL2 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV73647600; called by muse, mutect2, varscan2
- CEP135 | c.3389C>T p.S1130F | Missense Mutation (SNP) | VAF 119/433 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57259026, COSV57259438; called by muse, mutect2, varscan2
- CETN2 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64743511; called by muse, mutect2, varscan2
- CFAP61 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV55624267; called by muse, mutect2, varscan2
- CLCA4 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs762310034, COSV55367356; called by muse, mutect2, varscan2
- CLCNKA | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58891054; called by muse, mutect2, varscan2
- CLVS1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV57972926; called by muse, mutect2
- CNGA2 | c.1076T>A p.I359N | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61703865; called by muse, mutect2, varscan2
- CNKSR1 | c.1546G>A p.E516K (on ENST00000374253 / NM_001297647.2; = p.E509K on NM_006314.3) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58792732; called by muse, mutect2, varscan2
- CNKSR2 | c.1257A>T p.K419N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.116); catalogued as COSV54252800; called by muse, mutect2
- CNTN3 | c.2197G>A p.G733S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs767305444, COSV55167140; called by muse, mutect2, varscan2
- CNTN6 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63167352; called by muse, mutect2, varscan2
- COL11A1 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1485916096, COSV62178338; called by muse, mutect2
- COL27A1 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100621094, COSV61924164; called by muse, mutect2, varscan2
- COL4A6 | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484200222, COSV57862638; called by muse, mutect2, varscan2
- COL5A3 | c.3487G>A p.G1163R | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147491932; called by muse, mutect2, varscan2
- COL6A5 | c.5939A>G p.K1980R (on ENST00000312481; = p.K1976R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs201011140; called by muse, mutect2, varscan2
- CPLX2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.989); catalogued as COSV100853071; called by muse, mutect2, varscan2
- CPNE6 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs373558163; called by muse, mutect2, varscan2
- CPS1 | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 197/365 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV51806350, COSV99243548; called by muse, mutect2, varscan2
- CRTAC1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV53999583; called by muse, mutect2, varscan2
- CSMD3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52143540, COSV52289632; called by muse, mutect2, varscan2
- CYP3A7 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100312860, COSV60481043; called by muse, varscan2
- CYP8B1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV60226008; called by muse, mutect2, varscan2
- DBR1 | c.30C>G p.H10Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53429342; called by muse, mutect2, varscan2
- DCAF12L1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs868353872, COSV100948149, COSV64421461; called by muse, mutect2, varscan2
- DCP1A | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs267599901, COSV53688037; called by muse, mutect2, varscan2
- DDIT4L | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56767140; called by muse, mutect2, varscan2
- DDX50 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65291944; called by muse, mutect2, varscan2
- DDX60 | c.4748G>A p.R1583K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as rs750654165, COSV67095868; called by muse, mutect2, varscan2
- DGKA | c.2203A>T p.S735C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV59385296; called by muse, mutect2, varscan2
- DISP3 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs368450539; called by muse, mutect2, varscan2
- DLG5 | c.4001C>T p.S1334F | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs747152557, COSV64947417; called by muse, mutect2, varscan2
- DMD | c.7555G>A p.D2519N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs771877780, CM146144, COSV58901806; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DNAH5 | c.4916T>G p.F1639C | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54215429; called by muse, mutect2, varscan2
- DNMBP | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60623099; called by muse, mutect2, varscan2
- DOCK2 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV56951355; called by muse, mutect2, varscan2
- DOP1B | c.4976C>T p.S1659F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV67692806; called by muse, mutect2, varscan2
- DPYS | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60907766; called by muse, mutect2, varscan2
- DSCAML1 | c.1181T>A p.L394H (on ENST00000321322; = p.L334H on NM_020693.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100356336; called by muse, mutect2, varscan2
- DSCAML1 | c.1180C>A p.L394I (on ENST00000321322; = p.L334I on NM_020693.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as COSV100356337; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSP | c.2960C>T p.S987F | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65792136; called by muse, mutect2, varscan2
- DYNC1I1 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV61458286; called by muse, mutect2, varscan2
- EFHB | c.1997T>G p.L666R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99859738; called by muse, mutect2, varscan2
- EFHC2 | c.1851G>A p.M617I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59092897; called by muse, mutect2, varscan2
- EPHA4 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916849; called by muse, varscan2
- EPHA6 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.326); catalogued as COSV67566641; called by muse, mutect2, varscan2
- FAM120C | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60258485; called by muse, mutect2, varscan2
- FAM135B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs772418841, COSV52715727; called by muse, mutect2, varscan2
- FAM71D | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61295108; called by muse, mutect2, varscan2
- FARP1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60333816; called by muse, mutect2, varscan2
- FAT2 | c.9281C>T p.S3094L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.96); catalogued as rs745987151, COSV55816697; called by muse, mutect2, varscan2
- FBLIM1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs923782709, COSV60029047; called by muse, mutect2, varscan2
- FBXW7 | c.1117C>T p.P373S (on ENST00000281708 / NM_001349798.2; = p.P293S on NM_018315.5) | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV55905436; called by muse, mutect2, varscan2
- FLG2 | c.4262G>A p.G1421E | Missense Mutation (SNP) | VAF 128/420 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV66167618, COSV66170289; called by muse, mutect2, varscan2
- FRMPD2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV59716709; called by muse, mutect2, varscan2
- FRMPD4 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV66213133; called by muse, mutect2, varscan2
- FSD1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV55695471; called by muse, mutect2, varscan2
- GABRG2 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV62716747; called by muse, mutect2, varscan2
- GAPT | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs776211497, COSV59246746; called by muse, mutect2, varscan2
- GAS2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53405836; called by muse, mutect2, varscan2
- GET1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as COSV100414410; called by muse, mutect2, varscan2
- GIMAP8 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.14); catalogued as COSV56230659; called by muse, mutect2, varscan2
- GLCE | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV55945132; called by muse, mutect2, varscan2
- GPR137 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1378691774, COSV100464325; called by muse, varscan2
- GPR78 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as COSV101223921, COSV66762386; called by muse, mutect2, varscan2
- GRAMD4 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63029809; called by muse, mutect2, varscan2
- GREM1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55714706; called by muse, mutect2, varscan2
- GREM1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55714715; called by muse, mutect2, varscan2
- GRXCR1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs868831734, COSV67671020; called by muse, mutect2, varscan2
- GRXCR1 | c.627G>A p.G209= | Splice Region (SNP) | VAF 164/482 reads (34%) | catalogued as rs779522637, COSV67671025; called by muse, mutect2
- HCRTR2 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs770310033, COSV63794840; called by muse, mutect2, varscan2
- HNRNPCL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV58610745; called by muse, mutect2, varscan2
- HOXD12 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); catalogued as COSV66832463; called by muse, mutect2, varscan2
- HYAL3 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.212); catalogued as COSV56497185; called by muse, mutect2, varscan2
- HYDIN | c.5938G>A p.E1980K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as rs1167081936, COSV59253467; called by muse, mutect2, varscan2
- ICE2 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.412); catalogued as COSV55030518; called by muse, mutect2, varscan2
- IFT122 | c.2890G>A p.D964N (on ENST00000348417 / NM_052989.3; = p.D905N on NM_018262.4) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV56201595; called by muse, mutect2, varscan2
- IGHV3-43 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs763010736; called by muse, mutect2, varscan2
- IL1RAPL2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV61143544, COSV61155825; called by muse, mutect2, varscan2
- IL31RA | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV51680849, COSV51682972; called by muse, mutect2, varscan2
- INPP5D | c.3097C>T p.P1033S (on ENST00000445964 / NM_001017915.3; = p.P1032S on NM_005541.5) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV64036325; called by muse, mutect2, varscan2
- INTS4 | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV59017165; called by muse, mutect2
- IRAG2 | c.4196C>T p.S1399F (on ENST00000636465; = p.S444F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57231091; called by muse, mutect2, varscan2
- ITGB4 | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 91/132 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV52323649; called by muse, mutect2, varscan2
- KCNB2 | c.582C>T p.I194= | Splice Region (SNP) | VAF 60/309 reads (19%) | catalogued as COSV73049584; called by muse, mutect2, varscan2
- KCND2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV58574835; called by muse, mutect2, varscan2
- KCNIP4 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62847905; called by muse, mutect2, varscan2
- KDM3B | c.3725C>T p.S1242F | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs562855380, COSV58689599; called by muse, mutect2, varscan2
- KDR | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285248181, COSV55757697, COSV55761678; called by muse, mutect2, varscan2
- KITLG | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV57200764; called by muse, mutect2, varscan2
- KLB | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1334910501, COSV57300957; called by muse, mutect2, varscan2
- KLHL38 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58086726; called by muse, mutect2, varscan2
- KLK14 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs1315120887, COSV50068156; called by muse, mutect2, varscan2
- KRT16 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56967482; called by muse, mutect2, varscan2
- KRT6B | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV52882887; called by muse, mutect2, varscan2
- L3MBTL1 | c.2146C>T p.R716* (on ENST00000418998 / NM_001377303.1; = p.R626* on NM_015478.7) | Nonsense Mutation (SNP) | VAF 50/181 reads (28%) | catalogued as rs1433081565, COSV64228188; called by muse, mutect2, varscan2
- LAMC2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.871); catalogued as COSV51454063; called by muse, mutect2, varscan2
- LGALS9C | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60195335; called by muse, mutect2, varscan2
- LHFPL1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.987); catalogued as COSV64333198; called by muse, mutect2, varscan2
- LILRB1 | c.1186G>A p.E396K (on ENST00000427581; = p.E360K on NM_006669.6) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV61117013; called by muse, varscan2
- LIN9 | c.1489G>A p.D497N (on ENST00000366808 / NM_001270410.2; = p.D442N on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV60244502; called by muse, mutect2, varscan2
- LNX1 | c.745G>A p.E249K (on ENST00000263925 / NM_001126328.3; = p.E153K on NM_032622.2) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.075); catalogued as COSV55783809; called by muse, mutect2, varscan2
- LPAR1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406921667, COSV62688087; called by muse, mutect2, varscan2
- LRRC7 | c.1981G>A p.E661K (on ENST00000651989 / NM_001370785.2; = p.E628K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs200158661, COSV50435197; called by muse, mutect2, varscan2
- LTBP3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57239415; called by muse, mutect2, varscan2
- LYNX1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1212696114, COSV59988528; called by muse, mutect2, varscan2
- LYPD4 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV58027636; called by muse, mutect2, varscan2
- MAGEB2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as COSV66780562; called by muse, mutect2, varscan2
- MAGEC1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV53570572; called by muse, mutect2, varscan2
- MAGEC1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53570591; called by muse, varscan2
- MAPKAP1 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | catalogued as COSV56366118; called by muse, mutect2, varscan2
- MARCHF1 | c.190C>T p.P64S (on ENST00000274056; = p.P47S on NM_017923.4) | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs911354961, COSV56811775; called by muse, mutect2, varscan2
- MAST2 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV63617340; called by muse, mutect2, varscan2
- MCF2 | c.1336G>T p.G446W | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV58481328; called by muse, mutect2, varscan2
- MEGF8 | c.1287T>A p.D429E | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV52079559; called by muse, mutect2, varscan2
- MEPE | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as COSV63072336; called by muse, mutect2, varscan2
- MGAM | c.5260G>A p.D1754N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs779200546, COSV72074236; called by muse, mutect2, varscan2
- MICU2 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs772353232, COSV66673167; called by muse, mutect2, varscan2
- MKI67 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 131/302 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs773126492, COSV64073599, COSV64077864; called by muse, mutect2, varscan2
- MMP28 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs1012437556; called by muse, mutect2, varscan2
- MMP7 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV52771666; called by muse, mutect2, varscan2
- MROH2B | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV68185228; called by muse, mutect2, varscan2
- MROH2B | c.3870G>A p.M1290I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.406); catalogued as COSV68181239; called by muse, mutect2, varscan2
- MRPS34 | c.437A>T p.E146V | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV51599666, COSV51602663; called by muse, mutect2, varscan2
- MUC16 | c.38054C>T p.P12685L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs368715882; called by muse, mutect2, varscan2
- MUC16 | c.32540C>T p.S10847L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV67456424, COSV67481016; called by muse, mutect2, varscan2
- MUC3A | c.8668C>T p.P2890S | Missense Mutation (SNP) | VAF 109/475 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.314); catalogued as COSV60213210; called by muse, mutect2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MYLK2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767211264, COSV65658833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65658839; called by muse, mutect2, varscan2
- N4BP2 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as COSV54700694, COSV99789326; called by muse, mutect2, varscan2
- NAGA | c.88T>G p.W30G | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67169813; called by muse, mutect2, varscan2
- NAV3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57071559; called by muse, mutect2, varscan2
- NAV3 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57071576; called by muse, mutect2, varscan2
- NBEA | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59772008; called by muse, mutect2, varscan2
- NEK4 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1386061171, COSV51779777; called by muse, mutect2, varscan2
- NEXMIF | c.3553G>T p.G1185W | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV50025261; called by muse, varscan2
- NLGN2 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209361; called by muse, mutect2, varscan2
- NLRC4 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100707283, COSV61592047; called by muse, mutect2, varscan2
- NLRX1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52702901, COSV99424692; called by muse, mutect2, varscan2
- NONO | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52136749; called by muse, mutect2, varscan2
- NPAP1 | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.089); catalogued as COSV61505755; called by muse, mutect2, varscan2
- NRGN | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866104700, COSV52518211; called by muse, mutect2, varscan2
- NTRK1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771342578, COSV62324178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLAH | c.274G>A p.D92N (on ENST00000378228 / NM_001039702.3; = p.D145N on NM_018324.3) | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs774664197, COSV65491981; called by muse, mutect2, varscan2
- OR14I1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749745268, COSV61199331; called by muse, mutect2, varscan2
- OR2T5 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV63540523; called by muse, mutect2, varscan2
- OR4B1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58882374; called by muse, mutect2, varscan2
- OR4K1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs543752160, COSV53458720, COSV99579378; called by muse, mutect2
- OR4S2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56746122, COSV56747312; called by muse, mutect2, varscan2
- OR51A4 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV66749274, COSV66749674; called by muse, mutect2, varscan2
- OR51A7 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63788184, COSV99062602; called by muse, mutect2, varscan2
- OR51B2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as rs1388007752, COSV60916319, COSV60916770; called by muse, mutect2, varscan2
- OR51E1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67809598; called by muse, mutect2, varscan2
- OR52D1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV59487259, COSV59487508; called by muse, mutect2, varscan2
- OR52E2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV58611740; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR5J2 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56620605; called by muse, mutect2, varscan2
- OR5L1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as COSV61733324; called by muse, mutect2, varscan2
- OR5M1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV73202029; called by muse, mutect2, varscan2
- OR7G1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs769414989, COSV53316818; called by muse, mutect2, varscan2
- OR8D1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV63441945; called by muse, mutect2, varscan2
- P2RY10 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as COSV50680766; called by muse, mutect2, varscan2
- P3H3 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV51831879; called by muse, mutect2, varscan2
- PAPPA | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767569306, COSV60280393; called by muse, mutect2, varscan2
- PARP15 | c.1345C>T p.Q449* (on ENST00000464300 / NM_001113523.3; = p.Q215* on NM_152615.2) | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV59971590, COSV59972067; called by muse, mutect2, varscan2
- PASD1 | c.2220G>C p.Q740H | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV64854706; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA12 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 136/481 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554168825, COSV56489661, COSV56550497; called by muse, mutect2, varscan2
- PCDHB11 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as rs1554285789, COSV61310666; called by muse, mutect2, varscan2
- PCDHGA4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs748883538, COSV53922943; called by muse, mutect2, varscan2
- PCLO | c.10991T>A p.V3664D | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.563); catalogued as rs770768480, COSV100433912; called by muse, mutect2, varscan2
- PCLO | c.10990G>A p.V3664I | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100433913; called by muse, mutect2, varscan2
- PCLO | c.9789G>A p.M3263I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.73); catalogued as rs765554756, COSV100437514, COSV61625787; called by muse, mutect2, varscan2
- PDE11A | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV53690745; called by muse, mutect2, varscan2
- PDE6B | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV55325208; called by muse, mutect2, varscan2
- PDGFRA | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57266711; called by muse, mutect2, varscan2
- PDYN | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs75861277, COSV99453310; called by muse, mutect2, varscan2
- PIWIL4 | c.1393T>A p.S465T | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54408700; called by muse, mutect2, varscan2
- PKHD1L1 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV65740462; called by muse, mutect2, varscan2
- PLCB1 | c.1637A>T p.Y546F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100569169, COSV62044836; called by muse, mutect2, varscan2
- PLPP4 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV64827391; called by muse, mutect2, varscan2
- POLI | c.1777C>G p.Q593E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54188503; called by muse, mutect2, varscan2
- PPP1R9A | c.3070G>A p.G1024R | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1563570468, COSV56887566; called by muse, mutect2, varscan2
- PRKG1 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1482011029, COSV64768538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKG2 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52321931; called by muse, mutect2, varscan2
- PRSS35 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63800350; called by muse, mutect2, varscan2
- PRSS53 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV54923576; called by muse, mutect2, varscan2
- PRX | c.4237C>T p.P1413S | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52520137; called by muse, mutect2, varscan2
- PSG9 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 160/558 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52484175; called by muse, mutect2, varscan2
- PTPN5 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62125373; called by muse, mutect2, varscan2
- PTPN9 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV60723219; called by muse, mutect2, varscan2
- RAB3IP | c.478C>T p.R160C (on ENST00000550536 / NM_175623.4; = p.R144C on NM_022456.5) | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs375092922, COSV56083543; called by muse, mutect2, varscan2
- RAD54L2 | c.3162G>A p.M1054I | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56577829; called by muse, mutect2, varscan2
- RANBP2 | c.2965C>T p.H989Y | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV51698730; called by muse, mutect2, varscan2
- RBM27 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54588763; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs762006287; called by mutect2, varscan2
- RBP5 | c.354+1G>A p.X118_splice | Splice Site (SNP) | VAF 73/226 reads (32%) | catalogued as COSV56951860; called by muse, mutect2, varscan2
- REV1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51483504, COSV51487300; called by muse, mutect2, varscan2
- RGS18 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs988087391, COSV100817909, COSV66507541; called by muse, mutect2, varscan2
- RIMS2 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044087340, COSV68475437; called by muse, mutect2, varscan2
- RIPOR3 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs145939916; called by muse, mutect2, varscan2
- RNF17 | c.612G>A p.R204= | Splice Region (SNP) | VAF 18/94 reads (19%) | catalogued as COSV55037445; called by muse, mutect2, varscan2
- ROR1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs760676948, COSV64285894; called by muse, mutect2, varscan2
- RPLP2 | c.212T>A p.V71E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV58252797; called by muse, mutect2, varscan2
- RPS6KA1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64809777; called by muse, mutect2, varscan2
- RYR2 | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV63675918; called by muse, mutect2, varscan2
- SAMD9 | c.4487G>A p.G1496E | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.396); catalogued as COSV66074022; called by muse, mutect2, varscan2
- SDCCAG8 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs770306576, COSV59406943; called by muse, mutect2, varscan2
- SERAC1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs768699095, COSV65596112; called by muse, mutect2, varscan2
- SF3A3 | c.1371C>T p.S457= | Splice Region (SNP) | VAF 95/338 reads (28%) | catalogued as rs1026535011, COSV65955639; called by muse, mutect2, varscan2
- SHROOM2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66605559; called by muse, mutect2, varscan2
- SIGLEC8 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.123); catalogued as COSV100367188, COSV58473821; called by muse, mutect2, varscan2
- SIRT4 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs546670030, COSV52540487; called by muse, mutect2, varscan2
- SLC17A1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV99765875; called by muse, mutect2, varscan2
- SLC22A9 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1233303421, COSV54166582; called by muse, mutect2, varscan2
- SLC25A21 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV58718330; called by muse, mutect2, varscan2
- SLC26A5 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59699953; called by muse, mutect2, varscan2
- SLC26A9 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61601741; called by muse, mutect2, varscan2
- SLC27A1 | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53096400; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SLC6A12 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV62884148; called by muse, mutect2
- SLX4IP | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.734); catalogued as rs534429446, COSV57945534; called by muse, mutect2, varscan2
- SNPH | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1393468098, COSV60588197; called by muse, mutect2, varscan2
- SNX33 | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.819); catalogued as COSV100145830; called by muse, mutect2, varscan2
- SPAG5 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58801030; called by muse, mutect2, varscan2
- SPAM1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779755476, COSV56141188; called by muse, mutect2, varscan2
- SPATA31E1 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV57790564; called by muse, mutect2, varscan2
- SRCAP | c.7810C>G p.P2604A | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV52669918; called by muse, mutect2, varscan2
- SSTR1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57455456, COSV57456425; called by muse, mutect2, varscan2
- STOML3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1327142632, COSV65510339; called by muse, mutect2, varscan2
- SULF1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as COSV52678056; called by muse, mutect2, varscan2
- SUSD2 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64203292; called by muse, mutect2, varscan2
- SYCP1 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV65696223; called by muse, mutect2, varscan2
- SYCP2L | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs267600759, COSV51651688; called by muse, mutect2, varscan2
- TAB3 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55835599; called by muse, mutect2, varscan2
- TACC2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1411146175, COSV57751738; called by muse, mutect2, varscan2
- TAF1L | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54260095; called by muse, mutect2, varscan2
- TANGO6 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV55762901, COSV99936380; called by muse, mutect2, varscan2
- TAS2R16 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV50796976; called by muse, mutect2, varscan2
- TCHHL1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV64285332; called by muse, mutect2, varscan2
- TEKT2 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52880605; called by muse, mutect2, varscan2
- TENM2 | c.2904del p.F968Lfs*3 (on ENST00000518659 / NM_001122679.2; = p.F736Lfs*3 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 43/202 reads (21%) | catalogued as COSV69142786; called by mutect2, pindel, varscan2
- TENT5D | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV57635923; called by muse, mutect2, varscan2
- THOC2 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs868674081, COSV55543486; called by muse, mutect2, varscan2
- THSD7B | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as COSV55671272; called by muse, mutect2, varscan2
- TLE4 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV54629582; called by muse, mutect2, varscan2
- TLL1 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 50/199 reads (25%) | catalogued as rs762591575, COSV50261086, COSV50334932; called by muse, mutect2, varscan2
- TMEM132B | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs757718701, COSV54749643; called by muse, mutect2, varscan2
- TMEM200A | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs766067001, COSV51651030; called by muse, mutect2, varscan2
- TPK1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV63639352; called by muse, mutect2, varscan2
- TPR | c.5350C>T p.P1784S | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV66600481; called by muse, mutect2, varscan2
- TPTE | c.1118G>A p.R373Q (on ENST00000618007 / NM_199261.4; = p.R355Q on NM_199259.4) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568780841; called by muse, mutect2
- TRHDE | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53838850; called by muse, mutect2, varscan2
- TRIM27 | c.588T>A p.H196Q | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65873408; called by muse, varscan2
- TRIML2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV58715386; called by muse, mutect2, varscan2
- TTN | c.68984C>T p.S22995F (on ENST00000591111; = p.S15571F on NM_003319.4) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | PolyPhen probably damaging (0.945); catalogued as COSV59969257; called by muse, mutect2, varscan2
- TTN | c.58979A>T p.Y19660F (on ENST00000591111; = p.Y12236F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | PolyPhen probably damaging (0.994); catalogued as rs1211406312, COSV59969350; called by muse, mutect2, varscan2
- TTN | c.7897G>A p.E2633K (on ENST00000591111; = p.E2587K on NM_003319.4) | Missense Mutation (SNP) | VAF 57/113 reads (50%) | PolyPhen probably damaging (0.994); catalogued as rs1480559076, COSV59969387; called by muse, mutect2, varscan2
- UCHL1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as rs1294480724, COSV52651417; called by muse, mutect2, varscan2
- UGT2B11 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as rs778246996, COSV71423067; called by muse, mutect2, varscan2
- UGT2B15 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV57733794; called by muse, mutect2, varscan2
- UGT2B15 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57733812; called by muse, mutect2, varscan2
- UNC13C | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV52858268, COSV99523941; called by muse, mutect2, varscan2
- UNC13C | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV52858303; called by muse, mutect2, varscan2
- UNC79 | c.7823G>A p.R2608Q (on ENST00000393151 / NM_001346218.2; = p.R2431Q on NM_020818.5) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.448); catalogued as rs368890148; called by muse, mutect2, varscan2
- USH1G | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1158451550, COSV58881263; called by muse, mutect2, varscan2
- USP29 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762461791, COSV54141371, COSV99517785; called by muse, mutect2, varscan2
- USP9X | c.6031C>T p.Q2011* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV61065654, COSV61071714; called by muse, mutect2, varscan2
- VAT1L | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.757); catalogued as COSV56817246, COSV56819056; called by muse, mutect2, varscan2
- WDR19 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV56463464; called by muse, mutect2, varscan2
- WDR44 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.962); catalogued as COSV54162027; called by muse, mutect2, varscan2
- WDR62 | c.4208C>T p.P1403L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs768909004, COSV54333414; called by muse, mutect2, varscan2
- WHAMM | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV99725000; called by muse, mutect2, varscan2
- WHAMM | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 100/343 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV99725004; called by muse, mutect2, varscan2
- WNK3 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs146463327, COSV63612893; called by muse, mutect2, varscan2
- WSCD2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs754495429, COSV54580610; called by muse, mutect2, varscan2
- ZBTB33 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58533537, COSV58534649; called by muse, mutect2, varscan2
- ZFAND4 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60858428, COSV60858714; called by muse, mutect2, varscan2
- ZFAT | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs551616005, COSV64736636, COSV64738261; called by muse, mutect2, varscan2
- ZFHX4 | c.2217T>A p.F739L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV50656223; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60156197; called by muse, mutect2, varscan2
- ZNF185 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV59275084; called by muse, mutect2, varscan2
- ZNF208 | c.2816A>C p.H939P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68103120; called by muse, mutect2, varscan2
- ZNF267 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746380168, COSV100339823; called by muse, mutect2
- ZNF41 | c.1717C>T p.H573Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57441827; called by muse, mutect2, varscan2
- ZNF566 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV67573474; called by muse, mutect2, varscan2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF616 | c.15G>A p.G5= | Splice Region (SNP) | VAF 53/143 reads (37%) | catalogued as rs1236811603, COSV57510279; called by muse, mutect2, varscan2
- ZNF675 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100704856, COSV63095549; called by muse, mutect2, varscan2
- ZNF676 | c.1507C>T p.H503Y (on ENST00000650058; = p.H471Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68092562; called by muse, mutect2, varscan2
- ZP2 | c.2021C>A p.S674* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | catalogued as COSV54813186; called by muse, mutect2, varscan2
- ZP4 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV63911588, COSV63912817; called by muse, mutect2, varscan2
- ZSWIM5 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55799664; called by muse, mutect2, varscan2
- CSAG3 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by mutect2, varscan2
- GANC | c.2120del p.K707Rfs*54 | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | called by mutect2, pindel, varscan2
- IGHG3 | c.768A>T p.K256N | Missense Mutation (SNP) | VAF 141/497 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IL2RB | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NEXN | c.298+5_298+20del p.X100_splice | Splice Site (DEL) | VAF 25/115 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 146/441 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PRKAR1A | c.133del p.R45Dfs*84 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- SPTB | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2NL | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- USP10 | c.1163del p.S388* | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACAD10 | c.2367C>T p.R789= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV58155317; called by muse, mutect2, varscan2
- ACE | c.3207C>T p.V1069= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs371996217; called by muse, mutect2, varscan2
- ACSBG2 | c.1722G>A p.L574= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53123750; called by muse, mutect2, varscan2
- ACTL7B | c.147C>T p.I49= | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as COSV65927136; called by muse, mutect2, varscan2
- ACTL9 | c.648C>T p.H216= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs781826070, COSV61004818; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ADAMTS10 | c.861C>T p.L287= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs781868632, COSV54353263; called by muse, mutect2, varscan2
- ADAMTS18 | c.354G>A p.L118= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as COSV51403373; called by muse, mutect2, varscan2
- ADAMTS19 | c.2685G>A p.Q895= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as COSV50731376, COSV50736815, COSV50738945; called by muse, mutect2, varscan2
- ADAMTS6 | c.513G>A p.K171= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV66858416; called by muse, mutect2, varscan2
- ADGRE1 | c.999C>T p.I333= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs1250314273, COSV51674004; called by muse, mutect2, varscan2
- AGBL1 | c.2397C>T p.I799= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs926562357, COSV66853693; called by muse, mutect2, varscan2
- AK7 | c.1560C>T p.F520= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV50870330; called by muse, mutect2, varscan2
- ALG12 | c.543C>T p.I181= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs537689449, COSV58206672; called by muse, mutect2, varscan2
- AMER1 | c.2565T>C p.H855= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV57657783; called by muse, mutect2
- ANGPTL5 | c.372C>T p.L124= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV57532460; called by muse, mutect2, varscan2
- ANKRD42 | c.195T>C p.G65= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV52615196; called by muse, mutect2, varscan2
- ANO4 | c.2130C>T p.F710= (on ENST00000392977 / NM_001286615.2; = p.F675= on NM_178826.4) | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs751248544, COSV54587281; called by muse, mutect2, varscan2
- ARID3B | c.1161G>A p.R387= | Silent (SNP) | VAF 62/163 reads (38%) | catalogued as COSV60556999; called by muse, mutect2, varscan2
- ARID5B | c.2637C>T p.L879= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV54417279; called by muse, mutect2, varscan2
- ASB2 | c.1587C>T p.I529= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as rs775174511, COSV60111211; called by muse, mutect2, varscan2
- ASH1L | c.1947C>T p.S649= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs146736660; called by muse, mutect2, varscan2
- ATP11A | c.150C>T p.I50= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs756268096, COSV52109005, COSV99367045; called by muse, mutect2, varscan2
- ATP7B | c.2394C>T p.L798= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs758690020, COSV54436944; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- C12orf56 | c.1125T>A p.L375= (on ENST00000543942 / NM_001170633.2; = p.L215= on NM_001099676.3) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV61486234; called by muse, mutect2, varscan2
- C6 | c.1467C>T p.P489= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV54708015; called by muse, mutect2, varscan2
- C9 | c.1263C>T p.L421= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV54675680; called by muse, mutect2, varscan2
- CA5B | c.432C>T p.T144= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as rs763967676, COSV59416037, COSV59416365; called by muse, mutect2, varscan2
- CASR | c.864C>T p.I288= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1553766801, COSV56135987; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC27 | c.591C>T p.F197= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs758804138, COSV53899391, COSV99622758; called by muse, mutect2, varscan2
- CD300LD | c.147G>A p.L49= | Silent (SNP) | VAF 83/154 reads (54%) | catalogued as COSV60083536; called by muse, mutect2, varscan2
- CDH20 | c.609G>A p.V203= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as COSV53007433; called by muse, mutect2, varscan2
- CFAP77 | c.594C>T p.P198= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV58009416; called by muse, mutect2, varscan2
- CIB2 | c.288C>T p.S96= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs150519426; called by muse, mutect2, varscan2
- CORO2B | c.1107C>T p.Y369= | Silent (SNP) | VAF 102/359 reads (28%) | catalogued as rs1359386889, COSV55950908; called by muse, mutect2, varscan2
- CST6 | c.264C>T p.F88= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1565066914, COSV56409717; called by muse, mutect2, varscan2
- CXorf56 | c.339G>A p.G113= (on ENST00000536133 / NM_001170570.2; = p.G127= on NM_022101.4) | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV57437958; called by muse, mutect2, varscan2
- DGKG | c.444C>T p.V148= | Silent (SNP) | VAF 132/401 reads (33%) | catalogued as rs1369294246, COSV53963145; called by muse, mutect2, varscan2
- DMBT1 | c.1656C>T p.G552= | Silent (SNP) | VAF 104/191 reads (54%) | catalogued as rs768624008, COSV57539336; called by muse, mutect2, varscan2
- DMD | c.4164C>T p.F1388= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV63744786; called by muse, mutect2, varscan2
- EFHB | c.1998C>T p.L666= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV99859737; called by muse, mutect2, varscan2
- EIF6 | c.6G>A p.A2= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as rs1465691628, COSV65582525; called by muse, mutect2, varscan2
- ENAM | c.2829C>T p.N943= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV68535621; called by muse, mutect2, varscan2
- EOLA2 | c.378C>T p.N126= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV62207128; called by muse, mutect2, varscan2
- EPB41L4A | c.1308C>T p.F436= | Silent (SNP) | VAF 59/206 reads (29%) | catalogued as COSV54866288; called by muse, mutect2, varscan2
- EPHA4 | c.2055G>A p.L685= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV99916850; called by muse, varscan2
- EPHA4 | c.1992G>A p.R664= | Silent (SNP) | VAF 66/116 reads (57%) | catalogued as COSV56029797, COSV56042660; called by muse, varscan2
- ERICH3 | c.3642G>A p.G1214= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV58603305; called by muse, mutect2, varscan2
- FAM217A | c.249G>A p.G83= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV51159425; called by muse, mutect2, varscan2
- FBXL13 | c.1089G>A p.L363= | Silent (SNP) | VAF 76/373 reads (20%) | catalogued as rs1271491361, COSV57536504; called by muse, mutect2, varscan2
- FCER1A | c.387C>T p.F129= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV63666872; called by muse, mutect2, varscan2
- FGF21 | c.111C>T p.L37= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV55810073; called by muse, mutect2, varscan2
- FGFR2 | c.690C>T p.T230= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV60643838; called by muse, mutect2, varscan2
- FOXK2 | c.1473G>A p.A491= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as rs748655226, COSV58877969; called by muse, mutect2, varscan2
- FZD9 | c.1473C>T p.P491= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as rs782393554, COSV59990005; called by muse, mutect2, varscan2
- GET1 | c.108C>T p.S36= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100414411; called by muse, mutect2, varscan2
- GLB1L2 | c.168G>A p.L56= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV60278136; called by muse, mutect2, varscan2
- GPR137 | c.1071A>C p.P357= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV100464322; called by muse, varscan2
- GRIK2 | c.1167G>A p.L389= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV59725803; called by muse, mutect2, varscan2
- GRM3 | c.1332C>T p.F444= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64469512; called by muse, mutect2, varscan2
- GUCY2C | c.1068G>A p.R356= | Silent (SNP) | VAF 108/226 reads (48%) | catalogued as COSV53788618; called by muse, mutect2, varscan2
- GZMB | c.486G>A p.E162= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV53540820, COSV53542479; called by muse, mutect2, varscan2
- IGF1 | c.522G>A p.K174= | Silent (SNP) | VAF 309/727 reads (43%) | catalogued as COSV61032126; called by muse, mutect2, varscan2
- IGFN1 | c.2316C>T p.S772= (on ENST00000295591 / NM_001367841.1; = p.S3229= on NM_001164586.2) | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs553363503, COSV55169722; called by muse, mutect2, varscan2
- IGKV5-2 | c.222C>T p.L74= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as rs773166534; called by muse, mutect2
- INTS1 | c.3186C>T p.T1062= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV67176960; called by muse, mutect2, varscan2
- KCND1 | c.1641C>T p.S547= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV54413319; called by muse, mutect2, varscan2
- KCNJ14 | c.1092G>A p.K364= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100655795, COSV60737749; called by muse, mutect2, varscan2
- KCNK10 | c.1368G>A p.R456= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV56641857; called by muse, mutect2, varscan2
- KCNK18 | c.336G>A p.T112= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs749343773, COSV57971094; called by muse, mutect2, varscan2
- KCNK5 | c.540C>T p.F180= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs954748135, COSV63988526; called by muse, mutect2, varscan2
- KCTD12 | c.903C>T p.A301= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV58524424; called by muse, mutect2, varscan2
- KDM4B | c.1677G>A p.P559= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs549759229, COSV50213481; called by muse, mutect2, varscan2
- KDM5A | c.4203T>C p.A1401= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV66991510; called by muse, mutect2, varscan2
- KIR3DL3 | c.645C>T p.I215= | Silent (SNP) | VAF 103/353 reads (29%) | catalogued as rs751569195, COSV52547929; called by muse, mutect2, varscan2
- KLF1 | c.1059C>T p.H353= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs144695155; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLK12 | c.258C>T p.I86= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV51576594; called by mutect2, varscan2
- LMCD1 | c.411C>T p.I137= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV50087716; called by muse, mutect2, varscan2
- MAGEC1 | c.2028C>T p.L676= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs1404270625, COSV53570580, COSV99595329; called by muse, varscan2
- MARCHF11 | c.990C>T p.I330= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs370646944; called by muse, mutect2, varscan2
- MARCO | c.411C>T p.F137= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV59053290; called by muse, mutect2, varscan2
- MED12 | c.3408C>T p.I1136= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs756127182, COSV61335850; called by muse, mutect2, varscan2
- MIER2 | c.609C>T p.F203= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV53394971; called by muse, mutect2, varscan2
- MROH2B | c.669G>A p.R223= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV68182680; called by muse, mutect2, varscan2
- MROH7 | c.2490G>A p.K830= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV59870132; called by muse, mutect2, varscan2
- MRPL45 | c.795C>T p.I265= | Silent (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- MRPS23 | c.207G>A p.R69= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs764823014, COSV58032108; called by muse, mutect2, varscan2
- MUC16 | c.42384G>A p.L14128= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV66690347; called by muse, mutect2, varscan2
- MUC16 | c.16611C>T p.P5537= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV67456428; called by muse, mutect2
- MYH15 | c.2388C>T p.V796= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs748651572, COSV56307328; called by muse, mutect2, varscan2
- MYH4 | c.2769C>T p.I923= | Silent (SNP) | VAF 148/294 reads (50%) | catalogued as COSV55115611, COSV55122299; called by muse, mutect2, varscan2
- MYH6 | c.4761G>A p.Q1587= | Silent (SNP) | VAF 112/359 reads (31%) | catalogued as COSV62449123; called by muse, mutect2, varscan2
- MYO18B | c.6777G>A p.R2259= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV59130199; called by muse, mutect2
- MYO1C | c.711C>T p.F237= (on ENST00000648651 / NM_001080779.2; = p.F202= on NM_033375.5) | Silent (SNP) | VAF 71/130 reads (55%) | catalogued as COSV62998880; called by muse, mutect2, varscan2
- MYO7A | c.3210G>A p.V1070= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV68683258, COSV68684202; called by muse, mutect2, varscan2
- NAT2 | c.732C>T p.F244= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV54061611, COSV54063280; called by muse, mutect2, varscan2
- NELL2 | c.1419C>T p.I473= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61572187; called by muse, mutect2, varscan2
- NEXMIF | c.3621G>A p.G1207= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV50023708; called by muse, varscan2
- NOL4 | c.1320C>T p.I440= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV52343429; called by muse, mutect2, varscan2
- NOS3 | c.186C>T p.P62= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs1048775049, COSV52487780; called by muse, mutect2, varscan2
- NPAS4 | c.1806C>T p.V602= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs755287888, COSV60649683; called by muse, mutect2, varscan2
- NPC1L1 | c.3045C>T p.F1015= | Silent (SNP) | VAF 86/398 reads (22%) | catalogued as COSV56923752, COSV56926835; called by muse, mutect2, varscan2
- NWD1 | c.3534C>A p.A1178= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV60340270; called by muse, mutect2, varscan2
- OAS2 | c.1665G>A p.R555= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV60801878; called by muse, mutect2, varscan2
- OR1S2 | c.174C>T p.I58= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs780246369, COSV56919025; called by muse, mutect2, varscan2
- OR2AT4 | c.147G>A p.L49= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV59406753; called by muse, mutect2, varscan2
- OR2T12 | c.624C>T p.P208= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs1344369313, COSV58776949, COSV58777448; called by muse, mutect2, varscan2
- OR4C46 | c.180C>T p.S60= | Silent (SNP) | VAF 109/291 reads (37%) | catalogued as rs754762663, COSV60218790; called by muse, mutect2, varscan2
- OR51F1 | c.513C>T p.L171= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV58579225; called by muse, mutect2, varscan2
- OR51F1 | c.108C>T p.I36= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58579237; called by muse, mutect2, varscan2
- OR6C4 | c.594C>T p.I198= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV67792865; called by muse, mutect2, varscan2
- OR8B12 | c.783C>T p.P261= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV60911462; called by muse, mutect2, varscan2
- PDE9A | c.357G>A p.R119= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV52324235; called by muse, mutect2, varscan2
- PEAR1 | c.201G>A p.Q67= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52772181; called by muse, mutect2, varscan2
- PFDN4 | c.369C>T p.F123= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs556974515, COSV65062893; called by muse, mutect2, varscan2
- PIEZO2 | c.7356C>T p.F2452= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV53287920; called by muse, mutect2, varscan2
- PLCB3 | c.1998C>T p.N666= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs750271470, COSV54186911; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCH2 | c.1584G>A p.S528= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs992197877, COSV53941024; called by muse, mutect2, varscan2
- PLXNC1 | c.3207C>G p.V1069= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV51572901, COSV51573230; called by muse, mutect2, varscan2
- PRAMEF18 | c.732T>C p.R244= | Silent (SNP) | VAF 57/338 reads (17%) | called by muse, mutect2, varscan2
- PSD2 | c.883T>C p.L295= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV51198227; called by muse, mutect2, varscan2
- QRFP | c.127C>T p.L43= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV58064793; called by muse, mutect2, varscan2
- RBBP8NL | c.117G>A p.R39= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV53348709; called by muse, mutect2, varscan2
- REG3A | c.261C>T p.F87= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs774802444, COSV59409025; called by muse, mutect2, varscan2
- RELN | c.144G>C p.G48= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV58994248; called by muse, mutect2, varscan2
- RHPN1 | c.975G>A p.R325= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56645680; called by muse, mutect2, varscan2
- RPTN | c.15G>A p.L5= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs1557825308, COSV60166821, COSV60169136; called by muse, mutect2, varscan2
- RPUSD4 | c.921G>A p.K307= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV53598951; called by muse, mutect2, varscan2
- RTL3 | c.234G>A p.K78= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV58183644, COSV58184010; called by muse, mutect2, varscan2
- SATB1 | c.1633C>T p.L545= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV58668372; called by muse, mutect2, varscan2
- SDK2 | c.5037C>T p.F1679= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV66183939; called by muse, mutect2, varscan2
- SEC16A | c.1437C>T p.D479= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV51524523; called by muse, mutect2, varscan2
- SERPINA10 | c.1308C>T p.G436= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV56227916; called by muse, mutect2, varscan2
- SERPINA9 | c.555G>A p.G185= | Silent (SNP) | VAF 67/248 reads (27%) | catalogued as COSV54073888; called by muse, mutect2, varscan2
- SERPINB2 | c.357G>A p.G119= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV55091766; called by muse, mutect2, varscan2
- SH3RF2 | c.1908C>T p.I636= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs376940777, COSV63038205; called by muse, mutect2, varscan2
- SHROOM4 | c.1287G>A p.R429= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV56787114; called by muse, mutect2, varscan2
- SIGLEC8 | c.972G>T p.G324= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100367296; called by muse, mutect2, varscan2
- SIRPB1 | c.18C>T p.S6= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs1249939693, COSV54374800; called by muse, mutect2, varscan2
- SLC17A1 | c.171C>T p.P57= | Silent (SNP) | VAF 69/236 reads (29%) | catalogued as rs927789287, COSV99765811; called by muse, mutect2, varscan2
- SLC26A8 | c.360G>A p.L120= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV62885166; called by muse, mutect2, varscan2
- SLCO1B3 | c.1278C>T p.F426= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV53934500; called by muse, mutect2, varscan2
- SMYD2 | c.498C>T p.F166= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as rs775244264, COSV65290630; called by muse, mutect2, varscan2
- SMYD2 | c.730C>T p.L244= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs758614622, COSV65290636; called by muse, mutect2, varscan2
- SNX33 | c.90T>C p.F30= | Silent (SNP) | VAF 86/242 reads (36%) | catalogued as COSV100145831; called by muse, mutect2, varscan2
- SPATA21 | c.300G>A p.R100= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs1164387402, COSV59186202; called by muse, mutect2, varscan2
- SPEN | c.4770C>T p.L1590= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV65359921; called by muse, mutect2, varscan2
- SRRM2 | c.2349C>T p.S783= | Silent (SNP) | VAF 98/347 reads (28%) | catalogued as COSV57070935; called by muse, mutect2, varscan2
- SULF2 | c.591C>T p.T197= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV63415118; called by muse, mutect2, varscan2
- SYCE2 | c.459G>A p.V153= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV53366136; called by muse, mutect2, varscan2
- TAF1L | c.3132G>A p.V1044= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as COSV54260083; called by muse, mutect2, varscan2
- TBC1D25 | c.894C>T p.A298= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV65123455; called by muse, mutect2, varscan2
- TBX22 | c.1551C>T p.N517= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV64784932, COSV64785435; called by muse, mutect2, varscan2
- TCEAL5 | c.342G>A p.R114= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV65502853; called by muse, varscan2
- TLN1 | c.1536C>T p.T512= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV59206022; called by muse, mutect2, varscan2
- TMC5 | c.1233C>T p.S411= (on ENST00000396229 / NM_001105248.1; = p.S165= on NM_024780.5) | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV54902707; called by muse, mutect2, varscan2
- TRIM13 | c.222C>T p.S74= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs924079948, COSV53948668; called by muse, mutect2, varscan2
- TTN | c.66105G>A p.Q22035= (on ENST00000591111; = p.Q14611= on NM_003319.4) | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV59969282; called by muse, mutect2, varscan2
- TTN | c.65604G>A p.V21868= (on ENST00000591111; = p.V14444= on NM_003319.4) | Silent (SNP) | VAF 69/129 reads (53%) | catalogued as COSV59969318; called by muse, mutect2, varscan2
- TTN | c.12366C>T p.I4122= (on ENST00000591111; = p.I4076= on NM_003319.4) | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as COSV100618246; called by muse, mutect2, varscan2
- TTN | c.5322C>T p.I1774= (on ENST00000591111; = p.I1728= on NM_003319.4) | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV59912193, COSV60327875; called by muse, mutect2, varscan2
- TUBGCP6 | c.645C>T p.F215= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV50536485; called by muse, mutect2, varscan2
- TXLNB | c.1500G>A p.V500= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs973437196, COSV64443574; called by muse, mutect2, varscan2
- UGT2B11 | c.126C>T p.I42= | Silent (SNP) | VAF 70/265 reads (26%) | catalogued as rs747090575, COSV71423201; called by muse, mutect2, varscan2
- UNC13C | c.120G>A p.K40= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs774454223, COSV52858232; called by muse, mutect2, varscan2
- USH2A | c.5448G>A p.V1816= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as COSV56350238, COSV56421534; called by muse, mutect2, varscan2
- USP10 | c.2193C>T p.T731= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV54748015; called by muse, mutect2, varscan2
- VDAC3 | c.408A>G p.P136= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV50081330; called by muse, mutect2, varscan2
- VRTN | c.1326G>A p.K442= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV56439984; called by muse, mutect2, varscan2
- VWA2 | c.243G>A p.L81= | Silent (SNP) | VAF 66/138 reads (48%) | catalogued as COSV53905750; called by muse, mutect2, varscan2
- WLS | c.906C>T p.I302= | Silent (SNP) | VAF 87/240 reads (36%) | catalogued as COSV52039410; called by muse, mutect2, varscan2
- XIRP1 | c.843C>T p.I281= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs207463111, COSV61137733; called by mutect2, varscan2
- ZBED4 | c.45C>T p.F15= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1181658150, COSV53464049; called by muse, mutect2, varscan2
- ZNF182 | c.1431G>A p.Q477= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV59356641; called by muse, mutect2, varscan2
- ZNF267 | c.672C>T p.T224= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100339825; called by muse, mutect2
- ZSCAN20 | c.1104C>T p.G368= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as COSV63682127; called by muse, mutect2, varscan2
- ZSCAN5A | c.582G>A p.R194= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1208693820, COSV54223764, COSV54225501; called by muse, mutect2, varscan2
- ASB3 | c.*2T>C | 3'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99712152; called by muse, mutect2, varscan2
- CLCA3P | n.720G>A | RNA (SNP) | VAF 29/110 reads (26%) | called by muse, varscan2
- FSTL1 | c.*1232C>T | 3'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99820769; called by muse, mutect2, varscan2
- IFRD2 | c.-60C>T | 5'UTR (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57112827; called by muse, mutect2, varscan2
- LCN10 | c.258-246dup | Intron (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- LINC00303 | n.259C>T | RNA (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- MIR9-1 | chr1:156416833 G>A | 3'Flank (SNP) | VAF 46/129 reads (36%) | catalogued as COSV59483483; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163890 G>A | 5'Flank (SNP) | VAF 35/232 reads (15%) | catalogued as rs1442253206; called by muse, mutect2, varscan2
- SEPTIN6 | c.1281-1256C>T | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100595672; called by muse, mutect2, varscan2
- SERPINA13P | n.887G>A | RNA (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2
- SH3KBP1 | c.521-3663G>A | Intron (SNP) | VAF 32/180 reads (18%) | catalogued as COSV101114911; called by muse, mutect2, varscan2
- SPATA8 | n.724C>T | RNA (SNP) | VAF 36/104 reads (35%) | catalogued as rs756443854, COSV60704385; called by muse, mutect2, varscan2
- SSX6P | n.335G>A | RNA (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- ZNF99 | c.*323G>A | 3'UTR (SNP) | VAF 31/85 reads (36%) | catalogued as rs536055715, COSV68055631; called by muse, mutect2, varscan2
